HCMI case HCM-BROD-0335-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/47322ea3-6bbe-442b-a656-c48469cc99c1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 61.7 years (22,537 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIB; AJCC pathologic T: TX; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IIB; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 171 days; Days to treatment end: 278 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: metastasis; Age at diagnosis: 61.9 years (22,597 days); Days to diagnosis: 60 days.
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 23.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Follow-up contacts recording only the day: day 734, day 1,120.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.
- KIT mutation, nos: Negative.
- NRAS mutation, nos: Negative.
- TP53 mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 148 kg; Height: 190 cm; BMI: 41.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0335-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0335-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
